Somatic mutation profile of tumor specimen MP2PRT-PARVZG-TMP1-A (aliquot MP2PRT-PARVZG-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PARVZG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,227 days).
Specimen MP2PRT-PARVZG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9dc79bf4-ba9b-4981-af27-d5623c7c7f58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARVZG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARVZG-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23ee77f0-2465-4eff-84d5-885c30d94192

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4416G>T p.W1472C | Missense Mutation (SNP) | VAF 99/242 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52117493; called by muse, mutect2, varscan2
- FLT3 | c.1775T>C p.V592A | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1057520025, COSV54051432, COSV54058572, COSV54074139; ClinVar: likely pathogenic; called by muse, mutect2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 71/255 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASB9 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 33/437 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs964549174; called by muse, mutect2
- COBLL1 | c.2237C>T p.P746L (on ENST00000392717; = p.P708L on NM_014900.5) | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs201427085, COSV52063245; called by muse, mutect2, varscan2
- DLG4 | c.343G>A p.D115N (on ENST00000399506 / NM_001321075.3; = p.D158N on NM_001365.4) | Missense Mutation (SNP) | VAF 96/102 reads (94%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs754682597; called by muse, mutect2, varscan2
- IGSF1 | c.3465G>A p.W1155* | Nonsense Mutation (SNP) | VAF 89/196 reads (45%) | catalogued as COSV100811950; called by muse, mutect2, varscan2
- RBM20 | c.3648C>A p.S1216R | Missense Mutation (SNP) | VAF 72/275 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs554167951; called by muse, mutect2, varscan2
- SERPINA6 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 182/624 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs201703843, COSV58584055; called by muse, varscan2
- TTC6 | c.1060C>A p.R354S (on ENST00000267368; = p.R1720S on NM_001310135.3) | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57447777, COSV99942051; called by muse, varscan2
- LEPR | c.2607G>T p.K869N | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- LINC00514 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 127/304 reads (42%) | SIFT tolerated (0.28); called by muse, mutect2, varscan2
- ARAP3 | c.2820A>C p.V940= | Silent (SNP) | VAF 18/417 reads (4%) | called by muse, mutect2
- CRMP1 | c.1302C>T p.F434= | Silent (SNP) | VAF 146/417 reads (35%) | catalogued as rs368659492; called by muse, mutect2, varscan2
